Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAKH, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAKH-01A (Primary Tumor).

ICD-O-3
Carcinoma, embryonal NOS 9870/3
Site: @ Testis NOS C62.9
9/23/14

Concerning

Summary pathology report

Right orchidectomy; nonseminoma (EC 95%, SE 5%); diameter 4.5 cm; no angio-invasion;
invasion of rete testis present; tumor confined to testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 56f20125-22ff-4d02-b6b7-84f839ee0e10 (TCGA-2G-AAKH.07480F77-8F4D-418B-8822-6F52017D0AEF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).